Somatic mutation profile of tumor specimen TCGA-KN-8425-01A (aliquot TCGA-KN-8425-01A-11D-2310-10) from TCGA case TCGA-KN-8425, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.9 years (19,692 days).
Specimen TCGA-KN-8425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e271ef0d-521e-47c5-bdf4-e527229da613.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8425-11A (Solid Tissue Normal), aliquot TCGA-KN-8425-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/020e804e-9c06-44d8-a5cf-933b312ae3fd

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'UTR 1, 5'Flank 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768503856, COSV57123574; called by muse, mutect2, varscan2
- CEP126 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142032267, COSV54826164; called by muse, mutect2, varscan2
- DOCK3 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 76/120 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1359134188; called by muse, mutect2, varscan2
- FBXO21 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV100401766; called by muse, mutect2
- MUC16 | c.28633G>C p.V9545L | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.047); catalogued as rs753405562; called by muse, mutect2
- ARFGEF1 | c.2923C>T p.L975F | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP24 | c.432G>T p.E144D (on ENST00000395184 / NM_001025616.3; = p.E51D on NM_031305.3) | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- GLP1R | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPTOR | c.2138G>T p.C713F | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAP1 | chr7:955299 C>T | 5'Flank (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- NCR2 | c.-5A>G | 5'UTR (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100897234; called by muse, mutect2, varscan2
- TRMT9B | c.*550A>C | 3'UTR (SNP) | VAF 11/202 reads (5%) | catalogued as COSV101501601; called by muse, mutect2
